Somatic mutation profile of tumor specimen TCGA-SR-A6MY-01A (aliquot TCGA-SR-A6MY-01A-11D-A35I-08) from TCGA case TCGA-SR-A6MY, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 54.5 years (19,892 days).
Specimen TCGA-SR-A6MY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) beb6d78e-b635-47c5-b511-6db49bd66617.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SR-A6MY-10A (Blood Derived Normal), aliquot TCGA-SR-A6MY-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00c59ad8-f8f6-4809-ae0d-efa2f9e4409e

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Splice Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 44/100 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- EPS8L2 | c.863A>G p.K288R | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.044); catalogued as rs1219674573, COSV59348201; called by muse, mutect2
- PRELP | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.051); catalogued as rs775055111, COSV58116931; called by muse, mutect2, varscan2
- GOT1 | c.1115A>G p.E372G | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2
- PEX10 | c.194-2dup p.X65_splice | Splice Site (INS) | VAF 12/21 reads (57%) | called by mutect2, pindel, varscan2
- ACIN1 | c.3147A>G p.K1049= | Silent (SNP) | VAF 99/270 reads (37%) | called by muse, mutect2, varscan2
